Somatic mutation profile of tumor specimen TCGA-3A-A9IO-01A (aliquot TCGA-3A-A9IO-01A-11D-A38G-08) from TCGA case TCGA-3A-A9IO, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroendocrine carcinoma, NOS; Tissue or organ of origin: Body of pancreas; Tumor grade: G1; Age at diagnosis: 56.0 years (20,451 days).
Specimen TCGA-3A-A9IO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18fadc85-4ca1-4c33-9bd6-53438358dd9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3A-A9IO-10A (Blood Derived Normal), aliquot TCGA-3A-A9IO-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18d4927f-0b1b-4da6-a2f1-294066c4403b

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 4, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY3 | c.2872G>A p.D958N | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99567736; called by muse, mutect2
- CNTLN | c.3013G>A p.A1005T | Missense Mutation (SNP) | VAF 108/348 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); catalogued as COSV52064098; called by muse, mutect2, varscan2
- OR2G3 | c.419T>A p.L140H | Missense Mutation (SNP) | VAF 125/579 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100180490; called by muse, mutect2, varscan2
- VCL | c.1426A>G p.K476E | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.755); catalogued as rs1179637732, COSV99280483; called by muse, mutect2
- ACOX2 | c.1118_1119del p.T373Sfs*12 | Frame Shift Del (DEL) | VAF 65/146 reads (45%) | called by mutect2, pindel, varscan2
- NPRL2 | c.864_882del p.S289Efs*19 | Frame Shift Del (DEL) | VAF 59/153 reads (39%) | called by mutect2, pindel, varscan2
- ASTN1 | c.201C>T p.L67= | Silent (SNP) | VAF 43/132 reads (33%) | catalogued as rs763755386, COSV99920591, COSV99923512; called by muse, mutect2, varscan2
- EDEM2 | c.696C>T p.I232= | Silent (SNP) | VAF 18/294 reads (6%) | catalogued as rs1254201626, COSV100993652; called by muse, mutect2
- MUC16 | c.28065C>A p.T9355= | Silent (SNP) | VAF 42/468 reads (9%) | catalogued as COSV101198338; called by muse, mutect2
- RUNX1T1 | c.1179C>T p.I393= (on ENST00000265814 / NM_001198628.1; = p.I366= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/710 reads (5%) | catalogued as COSV56141046, COSV99749707; called by muse, mutect2
